Somatic mutation profile of tumor specimen MP2PRT-PATFGE-TMP1-A (aliquot MP2PRT-PATFGE-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATFGE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,372 days).
Specimen MP2PRT-PATFGE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9710e531-b64e-49df-975b-ce9a9e5798c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFGE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFGE-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b6d917-7556-4ecd-aa63-0292bcb96706

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP5 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1486425523, COSV70470109; called by muse, mutect2, varscan2
- GABRA4 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.433); catalogued as rs774499404; called by muse, mutect2, varscan2
- KRT1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99358431; called by muse, mutect2, varscan2
- PCDHGA3 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV53958650; called by muse, mutect2
- FREM2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 18/637 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2
- MGAT4C | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.606); called by muse, mutect2
- SERPINA1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2
- TAOK3 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- WWC1 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEOX2 | c.45G>A p.T15= | Silent (SNP) | VAF 38/366 reads (10%) | catalogued as rs771332987, COSV56287957; called by muse, mutect2, varscan2
